Gene-level copy-number profile of tumor specimen TCGA-QR-A70P-01A from TCGA case TCGA-QR-A70P, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 45.6 years (16,655 days).
Specimen TCGA-QR-A70P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.21df1909-305e-4230-8254-d4932dea030c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QR-A70P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e5043d1-057c-46c3-b886-bbfed5610a0e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,713; copy number 2: 50,431; copy number 3: 2,672.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QR-A70P-01A-11D-A35C-01): tumor purity 0.81, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,713. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
